Somatic mutation profile of tumor specimen TCGA-DD-A3A8-01A (aliquot TCGA-DD-A3A8-01A-11D-A22F-10) from TCGA case TCGA-DD-A3A8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 75.4 years (27,524 days).
Specimen TCGA-DD-A3A8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3db6dbe-9546-46fd-b5d8-fd02039fb7e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A8-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A8-11A-11D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92408137-0c32-436e-b492-a617da788c6f

The open-access MAF lists 152 somatic variants for this specimen: 109 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 37, Nonsense Mutation 6, 3'UTR 4, Frame Shift Ins 3, RNA 2, In Frame Del 1, Splice Region 1, Splice Site 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.477C>G p.Y159* | Nonsense Mutation (SNP) | VAF 55/80 reads (69%) | catalogued as rs863224281, CM960066, COSV57331907, COSV57366310; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1387T>G p.F463V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52208209; called by muse, mutect2, varscan2
- ADI1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100537866, COSV59377534; called by muse, mutect2, varscan2
- AHNAK2 | c.7112C>T p.P2371L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs528075601, COSV60924223; called by muse, mutect2, varscan2
- ANKIB1 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56059675, COSV56062947; called by muse, mutect2, varscan2
- ANKRD17 | c.3383A>G p.H1128R | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1350027336, COSV58225235; called by muse, mutect2, varscan2
- ANKRD18B | c.1511A>G p.D504G | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV52091006; called by muse, mutect2, varscan2
- ARHGEF10L | c.818A>G p.H273R | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as rs1408594257, COSV51437671; called by muse, mutect2, varscan2
- ASMT | c.700G>A p.E234K (on ENST00000381229; = p.E262K on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/470 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.577); catalogued as COSV67110217; called by muse, mutect2, varscan2
- ATAD2 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 18/311 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54884770; called by muse, mutect2
- ATP10A | c.517T>C p.C173R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as COSV63521144; called by muse, mutect2, varscan2
- ATR | c.2070G>C p.K690N | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV63388022, COSV63389572; called by muse, mutect2, varscan2
- ATXN2 | c.1987G>A p.V663I (on ENST00000550104; = p.V503I on NM_002973.4) | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as COSV66485183; called by muse, mutect2
- BDP1 | c.951G>T p.M317I | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62433244; called by muse, mutect2, varscan2
- BMP2K | c.2888C>T p.T963M | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); catalogued as rs370861712; called by muse, mutect2
- BTRC | c.1780dup p.R594Pfs*27 (on ENST00000370187 / NM_033637.4; = p.R558Pfs*27 on NM_003939.5) | Frame Shift Ins (INS) | VAF 51/146 reads (35%) | catalogued as rs774921343; called by mutect2, varscan2
- CA4 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs769214297, COSV56282189; called by muse, mutect2, varscan2
- CACNA1F | c.5625C>A p.F1875L | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.024); catalogued as COSV59906126; called by muse, mutect2, varscan2
- CDHR1 | c.1436C>A p.A479D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60565023; called by muse, mutect2, varscan2
- CEP135 | c.920A>C p.N307T | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV57261850; called by muse, mutect2
- CEP97 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59126566; called by muse, mutect2, varscan2
- CHD6 | c.5978A>T p.H1993L | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs1055614264, COSV64693121; called by muse, mutect2
- CREB3L3 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV50239464; called by muse, mutect2, varscan2
- CREBBP | c.3695A>G p.N1232S | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52134627; called by muse, mutect2, varscan2
- CSPG5 | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV53132593; called by muse, mutect2, varscan2
- CTNNA3 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57721046; called by muse, mutect2
- DENND2C | c.1901C>A p.P634Q (on ENST00000393274 / NM_001256404.2; = p.P577Q on NM_198459.4) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67923222; called by muse, mutect2, varscan2
- DNAH6 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV52874879; called by muse, mutect2, varscan2
- DPYD | c.2758A>G p.T920A | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV64608880; called by muse, mutect2, varscan2
- DYRK3 | c.1652T>A p.L551* | Nonsense Mutation (SNP) | VAF 6/144 reads (4%) | catalogued as COSV100895598; called by muse, mutect2
- EIF4E1B | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV100024534, COSV53781362; called by muse, mutect2, varscan2
- ESM1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV67318799; called by muse, mutect2, varscan2
- EYS | c.8458C>A p.L2820I (on ENST00000370621 / NM_001292009.1; = p.L2799I on NM_001142800.2) | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as COSV65524254; called by muse, mutect2, varscan2
- EYS | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 60/215 reads (28%) | catalogued as COSV65524262; called by muse, mutect2, varscan2
- FAM227B | c.1187A>G p.Y396C | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54816239; called by muse, mutect2, varscan2
- FAP | c.2035-2A>G p.X679_splice | Splice Site (SNP) | VAF 61/198 reads (31%) | catalogued as rs566100960, COSV51865389; called by muse, mutect2, varscan2
- FAP | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51865396; called by muse, mutect2, varscan2
- FARP1 | c.3023A>G p.Y1008C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60343788; called by muse, mutect2, varscan2
- FREM1 | c.4322A>G p.Q1441R | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs376519870, COSV101084856; called by muse, mutect2, varscan2
- GAB4 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV101271855, COSV68754668; called by muse, mutect2, varscan2
- GBP2 | c.511A>C p.S171R | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.331); catalogued as COSV65070014; called by muse, mutect2, varscan2
- GEM | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs774085906, COSV52598297; called by muse, mutect2
- GPR37 | c.1636C>G p.P546A | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58258771; called by muse, mutect2, varscan2
- GRIP1 | c.3374C>A p.T1125N (on ENST00000359742 / NM_001379345.1; = p.T1073N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.255); catalogued as COSV54035166; called by muse, mutect2, varscan2
- HDAC8 | c.221C>G p.A74G | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV65227926; called by muse, mutect2, varscan2
- IGF2R | c.4417C>T p.R1473* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV63631393; called by muse, mutect2, varscan2
- ITGB1BP1 | c.153A>G p.G51= | Splice Region (SNP) | VAF 4/40 reads (10%) | catalogued as COSV53006832; called by muse, mutect2
- ITPR2 | c.7181C>G p.S2394C | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67273827; called by muse, mutect2, varscan2
- JPH1 | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV60613384, COSV60613805; called by muse, mutect2, varscan2
- KCNAB2 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV51238251; called by muse, mutect2, varscan2
- LAMA3 | c.5230A>G p.T1744A (on ENST00000313654 / NM_198129.4; = p.T135A on NM_000227.6) | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV52539816; called by muse, mutect2, varscan2
- LCP1 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549656; called by muse, mutect2, varscan2
- LCP1 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100549658; called by muse, mutect2, varscan2
- LIMK2 | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.269); catalogued as COSV59183668; called by muse, mutect2, varscan2
- MACF1 | c.18211G>A p.A6071T (on ENST00000372915; = p.A4116T on NM_012090.5) | Missense Mutation (SNP) | VAF 11/162 reads (7%) | catalogued as COSV57134715; called by muse, mutect2
- MEF2A | c.306C>A p.D102E | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.331); catalogued as COSV57536066; called by muse, mutect2, varscan2
- MTMR1 | c.1321G>T p.G441C | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64892817; called by muse, mutect2, varscan2
- MYH2 | c.4220A>T p.E1407V | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55444447; called by muse, mutect2
- NBEAL2 | c.2380G>T p.G794C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52761420; called by muse, mutect2, varscan2
- NDST4 | c.1629G>A p.W543* | Nonsense Mutation (SNP) | VAF 22/223 reads (10%) | catalogued as COSV52124292, COSV52130341; called by muse, mutect2, varscan2
- NES | c.2221C>A p.H741N | Missense Mutation (SNP) | VAF 140/260 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV63962169; called by muse, mutect2, varscan2
- NKTR | c.4322C>T p.S1441F | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV99235135; called by muse, mutect2
- NR3C2 | c.2943C>G p.F981L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60996692; called by muse, mutect2, varscan2
- OGN | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52761551; called by muse, mutect2, varscan2
- OR2M5 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 171/316 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1403694658, COSV63546712; called by muse, mutect2, varscan2
- OR5D18 | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61738133; called by muse, mutect2, varscan2
- OR9I1 | c.612T>A p.N204K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV56927152; called by muse, mutect2, varscan2
- ORC2 | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1010053634, COSV52240522; called by muse, mutect2
- PAQR5 | c.818T>A p.L273H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV61818742; called by muse, mutect2, varscan2
- PCDHAC2 | c.1532G>A p.R511K | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV53862488; called by muse, mutect2
- PCLO | c.13649T>C p.M4550T | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs556966262, COSV61654260; called by muse, mutect2, varscan2
- PCLO | c.7518C>A p.S2506R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61654271; called by muse, mutect2, varscan2
- PEX2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV63813859; called by muse, mutect2, varscan2
- POLR2G | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53670265; called by muse, mutect2
- PPIL1 | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 138/270 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1209621168, COSV63837715; called by muse, varscan2
- PPP1R15B | c.1582A>C p.S528R | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV65816271; called by muse, mutect2, varscan2
- PRUNE2 | c.6220G>A p.A2074T | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV65045024; called by muse, mutect2, varscan2
- PTP4A3 | c.412C>A p.R138S (on ENST00000329397; = p.R113S on NM_007079.3) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV61472499; called by muse, mutect2, varscan2
- RAB20 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV57441550; called by muse, varscan2
- RBM25 | c.1666C>G p.P556A | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV56201723; called by muse, mutect2, varscan2
- ROBO1 | c.4236G>T p.E1412D | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV71397146; called by muse, varscan2
- RPE65 | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV52017569; called by muse, mutect2, varscan2
- SDHB | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs769687734, COSV64964794, COSV64965564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEPSECS | c.554A>C p.E185A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV57206860; called by muse, mutect2, varscan2
- SLFN14 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs548942825, COSV70570485; called by muse, mutect2, varscan2
- SMC1B | c.102C>A p.N34K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61581999; called by muse, mutect2, varscan2
- SPEN | c.2714A>G p.N905S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs768180417, COSV65365599; called by muse, mutect2, varscan2
- TARS3 | c.1775A>G p.N592S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV60108954; called by muse, mutect2, varscan2
- TBCCD1 | c.218G>T p.W73L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58662986; called by muse, mutect2, varscan2
- TJAP1 | c.498G>C p.E166D (on ENST00000372445 / NM_001146016.1; = p.E156D on NM_080604.3) | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV52502744; called by muse, mutect2, varscan2
- TMEM128 | c.143T>G p.L48R (on ENST00000382753 / NM_001297552.2; = p.L24R on NM_032927.3) | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54637783; called by muse, mutect2, varscan2
- TRIM37 | c.979G>T p.V327L | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV51884617, COSV51887080; called by muse, mutect2
- TRIM68 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs139399398; called by muse, mutect2, varscan2
- TTC19 | c.745T>C p.F249L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV51987671; called by muse, mutect2, varscan2
- TTN | c.86527A>T p.T28843S (on ENST00000591111; = p.T21419S on NM_003319.4) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | PolyPhen benign (0.028); catalogued as COSV60231805; called by muse, mutect2, varscan2
- TTN | c.32720A>T p.E10907V (on ENST00000591111; = p.E9980V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/208 reads (12%) | PolyPhen possibly damaging (0.698); catalogued as COSV60231851; called by muse, mutect2, varscan2
- VWA5B2 | c.3677G>A p.W1226* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV56613295; called by muse, mutect2, varscan2
- WDR7 | c.758C>G p.P253R | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.216); catalogued as COSV54359686; called by muse, mutect2, varscan2
- YIPF1 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as COSV50778675; called by muse, mutect2, varscan2
- YIPF7 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV60657631; called by muse, mutect2
- ZMYM5 | c.122C>G p.P41R | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV61989353; called by muse, mutect2, varscan2
- ZNF211 | c.272G>T p.G91V (on ENST00000347302 / NM_198855.4; = p.G104V on NM_006385.5) | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53744164; called by muse, mutect2, varscan2
- ESRP2 | c.1929-4_1947dup p.T650Lfs*46 (on ENST00000565858 / NM_001365264.1; = p.T640Lfs*46 on NM_024939.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 3/18 reads (17%) | called by mutect2, pindel
- IPO4 | c.1200_1201insGTGT p.K401Vfs*2 | Frame Shift Ins (INS) | VAF 24/55 reads (44%) | called by mutect2, pindel*, varscan2
- MTR | c.3175A>G p.I1059V | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- MUC19 | c.450A>C p.R150S | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR4X2 | c.911A>T p.*304Lext*11 | Nonstop Mutation (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- SPEN | c.1804_1810delinsA p.S602_Q604delinsK | In Frame Del (DEL) | VAF 10/58 reads (17%) | called by pindel, varscan2*
- ZNF606 | c.2281_2284del p.E761Nfs*30 | Frame Shift Del (DEL) | VAF 43/161 reads (27%) | called by mutect2, pindel, varscan2
- CDH1 | c.855A>G p.T285= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV55737817; called by muse, mutect2, varscan2
- CPZ | c.1707C>T p.A569= (on ENST00000360986 / NM_001014447.3; = p.A558= on NM_003652.3) | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as COSV59924658; called by muse, mutect2, varscan2
- DAGLA | c.834C>A p.L278= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as COSV57198491; called by muse, mutect2, varscan2
- DCK | c.504A>G p.Q168= | Silent (SNP) | VAF 21/209 reads (10%) | catalogued as COSV54379449; called by muse, mutect2
- DDX56 | c.1098T>A p.P366= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV51837407; called by muse, mutect2, varscan2
- DNAI4 | c.630G>A p.L210= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV64019224; called by muse, mutect2, varscan2
- DUSP5 | c.522T>C p.Y174= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs1277026185, COSV63646886; called by muse, mutect2, varscan2
- HELZ2 | c.7869C>T p.L2623= (on ENST00000467148 / NM_001037335.2; = p.L2054= on NM_033405.3) | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs141769251; called by muse, mutect2, varscan2
- IL20RB | c.444T>C p.D148= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV59048943; called by muse, mutect2, varscan2
- LOXHD1 | c.4504C>A p.R1502= | Silent (SNP) | VAF 18/222 reads (8%) | catalogued as COSV56068269; called by muse, mutect2
- MEGF8 | c.5793C>T p.C1931= (on ENST00000251268 / NM_001271938.2; = p.C1864= on NM_001410.3) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV52095585; called by muse, mutect2, varscan2
- MUC4 | c.8748C>A p.T2916= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as rs754754440, COSV57778228; called by muse, mutect2
- MYT1L | c.948G>A p.E316= | Silent (SNP) | VAF 43/160 reads (27%) | catalogued as COSV67727724; called by muse, mutect2, varscan2
- NCKAP5L | c.3777G>T p.L1259= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100258249, COSV60131712; called by muse, mutect2, varscan2
- NDUFS8 | c.12G>A p.L4= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV50290093; called by muse, mutect2
- NHSL1 | c.2745T>C p.T915= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV58681349; called by muse, mutect2, varscan2
- NMUR1 | c.852G>A p.R284= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV59403601, COSV59405119; called by muse, mutect2, varscan2
- OR2Y1 | c.615C>T p.V205= | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as rs752095483, COSV57136101; called by muse, mutect2, varscan2
- PHGDH | c.351G>C p.L117= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV65571903; called by muse, mutect2, varscan2
- PIGR | c.2256C>T p.T752= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as rs746425326, COSV62904701; called by muse, mutect2, varscan2
- RECQL | c.36T>C p.D12= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV59085529; called by muse, mutect2, varscan2
- RNF26 | c.549A>G p.V183= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV60991140; called by muse, mutect2, varscan2
- RSRC1 | c.450G>A p.E150= | Silent (SNP) | VAF 69/164 reads (42%) | catalogued as COSV55835140; called by muse, mutect2, varscan2
- RYR2 | c.945A>T p.L315= | Silent (SNP) | VAF 26/424 reads (6%) | catalogued as COSV63663351, COSV63702969; called by muse, mutect2
- SEL1L | c.927G>A p.Q309= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV60921709; called by muse, mutect2, varscan2
- SLC22A1 | c.180G>A p.Q60= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV61453405; called by muse, mutect2, varscan2
- SLC2A1 | c.1071G>T p.L357= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV65288025; called by muse, mutect2, varscan2
- SLIT2 | c.1743A>G p.A581= | Silent (SNP) | VAF 178/481 reads (37%) | catalogued as rs756174540, COSV56586402; called by muse, mutect2, varscan2
- SMYD1 | c.849G>C p.L283= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV70225679; called by muse, mutect2, varscan2
- TDRD7 | c.2001C>T p.L667= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV62429525; called by muse, mutect2, varscan2
- TFAP4 | c.843C>T p.G281= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV52598611, COSV99200090; called by muse, mutect2, varscan2
- TOP2B | c.2178C>T p.L726= (on ENST00000264331 / NM_001330700.2; = p.L721= on NM_001068.3) | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV51975323; called by muse, mutect2, varscan2
- TTLL8 | c.447G>A p.L149= | Silent (SNP) | VAF 62/175 reads (35%) | called by muse, mutect2, varscan2
- ZNF185 | c.291C>T p.S97= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV59277550; called by muse, mutect2, varscan2
- ZNF292 | c.4044G>A p.G1348= | Silent (SNP) | VAF 50/82 reads (61%) | catalogued as rs939226786, COSV60544043; called by muse, mutect2, varscan2
- ZNF564 | c.1173A>G p.G391= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV59436023; called by muse, mutect2
- ZNF638 | c.1659A>G p.P553= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as rs1047278280, COSV52493020; called by muse, mutect2, varscan2
- DCAF4L1 | c.*3242A>G | 3'UTR (SNP) | VAF 66/142 reads (46%) | catalogued as COSV100047939; called by muse, mutect2, varscan2
- FAM182A | n.1120A>G | RNA (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- PCDHB16 | c.*759C>T | 3'UTR (SNP) | VAF 33/53 reads (62%) | catalogued as rs1443564137, COSV100292272; called by muse, mutect2, varscan2
- RRM2 | n.672C>T | RNA (SNP) | VAF 56/109 reads (51%) | catalogued as rs776733029; called by muse, mutect2, varscan2
- Z83844.2 | c.*1023C>G | 3'UTR (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99312772; called by muse, mutect2, varscan2
- ZBED4 | c.*2525C>G | 3'UTR (SNP) | VAF 15/189 reads (8%) | catalogued as COSV99350780; called by muse, mutect2
